Surgical pathology report (de-identified scan), TCGA case TCGA-73-4675, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4675-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

*****Addendum*****

SPECIMEN(S):

- A. 4L LYMPH NODE
- B. LEVEL 7 LYMPH NODE
- C. 2R LYMPH NODE
- D. LEVEL 11 LYMPH NODE
- E. ADDITIONAL LEVEL 11 LYMPH NODE
- F. LEFT LOWER LOBE
- G. RIB
- H. LEVEL 7 LYMPH NODE
- I. LEVEL 5 LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Adenocarcinoma

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-FSC: 4L, level 7, 2R: Negative for tumor.

FSF: Left lower lobe, lobectomy: Bronchial margin negative for carcinoma. Diagnosis was called by

GROSS DESCRIPTION:

A. 4L LYMPH NODE

Received fresh labeled with the patient's identification and "4L" is an aggregate of lymphoid tissue, 1.7 x 1.2 x 0.3 cm; submitted entirely for frozen section diagnosis in cassette FSA.

B. LEVEL 7 LYMPH NODE

[page 2 of 6]
[REDACTED]

Received fresh labeled with the patient's identification and "level 7" is a 1.3 x 0.9 x 0.2 cm lymph node; submitted entirely for frozen section diagnosis in cassette FSB.

C. 2R LYMPH NODE

Received fresh the patient's identification and "2R" is a 1 x 0.5 x 0.3 cm lymph node; submitted entirely for frozen section diagnosis in cassette FSC.

D. LEVEL 11 LYMPH NODE

Received, labeled with the patient's name, as "level 11 lymph node" is a 0.5 x 0.4 x 0.3-cm piece of tan tissue. It is submitted in toto as D1.

E. ADDITIONAL LEVEL 11 LYMPH NODE

Received, labeled with the patient's name, as "additional level 11 lymph node" is a 3.5 x 2.8 x 0.7 cm aggregate of multiple tan lymph nodes and red-brown fragments of tissue. It is submitted in toto as follows:

E1-Five lymph nodes (one bisected, inked)

E2-Two lymph nodes, bisected (one inked)

E3-E4-Remaining tissue fragments

F. LEFT LOWER LOBE

Received fresh labeled with the patient's identification and "left lower lobe" for intra-operative bronchial margin examination. The specimen consists of a 601-g lobectomy specimen measuring 17 x 14 x 6.5 cm. The is indurated and puckered pleura is inked black. The mass measuring 10 x 9 x 6 cm is within 2 mm from the pleura and 1.2 cm from the bronchial margin. The mass has a tan grey partially necrotic cut-surface. Multiple peribronchial lymph nodes measuring from 0.4 to 1 cm are recovered. The remainder of the parenchyma is pink, dark red and focally condensed. Photographs are taken and tissue is procured. Shave section is taken of the bronchial margin.

Representatively submitted as follows:

FSA - frozen shave of bronchial margin

F2 - bronchial shaved next to the frozen

F3 to F5 - 5 possible lymph nodes each, peribronchial

F6, F7 - mass with bronchial

F8, F9 - mass to pleura (closest)

F10, F11 - mass

F12, F13 - grossly uninvolved parenchyma

G. RIB

Received, labeled with the patient's, name as "rib" is a 2.4 x 2.2 x 0.5-cm aggregate of three fragments of bone with attached red-brown soft tissue. After decalcification, it is submitted in toto as G1-G2.

H. LEVEL 7 LYMPH NODE

Received, labeled with the patient's name, as "level 7 lymph node" is a 1.6 x 1.1 x 0.5 cm aggregate of tan-red fragments of tissue. One fragment is bisected, inked. It is submitted in toto as H1.

I. LEVEL 5 LYMPH NODE

[page 3 of 6]
[REDACTED]

Received, labeled with the patient's name, as "level 5 lymph node" is a 1.7 x 1.7 x 0.5 cm aggregate of three fragments of brown-red tissue. Each piece is bisected and submitted in toto as 11-12.

[REDACTED]

DIAGNOSIS:

A. 4L LYMPH NODE; EXCISION:

- REACTIVE LYMPH NODE -NEGATIVE FOR TUMOR (0/1)

B. LEVEL 7 LYMPH NODE; EXCISION:

- REACTIVE LYMPH NODE -NEGATIVE FOR TUMOR (0/1)

C. 2R LYMPH NODE, EXCISION:

- REACTIVE LYMPH NODE -NEGATIVE FOR TUMOR (0/1)

D. LEVEL 11 LYMPH NODE, EXCISION:

- REACTIVE LYMPH NODE -NEGATIVE FOR TUMOR (0/1)

E. ADDITIONAL LEVEL 11 LYMPH NODE, EXCISION:

- REACTIVE LYMPH NODES- NEGATIVE FOR TUMOR (0/9)

F. LUNG, LEFT LOWER LOBE, EXCISION:

- WELL DIFFERENTIATED ADENOCARCINOMA, MEASURING 10.0 X 9.0 CM
- BRONCHIAL MARGIN IS FREE OF TUMOR
- PERIBRONCHIAL LYMPH NODES POSITIVE FOR CARCINOMA (3/14)
- SEE TEMPLATE

G. RIB, EXCISION:

- IN DECALCIFICATION.

H. LEVEL 7 LYMPH NODE, EXCISION:

- REACTIVE LYMPH NODE -NEGATIVE FOR TUMOR (0/1)

I. LEVEL 5 LYMPH NODE, EXCISION:

- REACTIVE LYMPH NODES- NEGATIVE FOR TUMOR (0/4)

SYNOPTIC REPORT - LUNG

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Lower lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 10cm

Additional dimensions: 9cm

[page 4 of 6]
WHO CLASSIFICATION

Adenocarcinoma

Histologic Grade: G1: Well differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Present (pT2)

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Positive 3 / 24

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 7

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1

Non-Neoplastic Lung: Emphysematous changes

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 2 N 1 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

[page 5 of 6]
ADDENDUM:

G. RIB, EXCISION:

- BONE AND BONE MARROW WITH NO PATHOLOGIC ABNORMALITIES.
- NO TUMOR SEEN.
-

[page 6 of 6]
ADDENDUM:

Based on the 7th edition AJCC staging, the stage should be pT3 and not pT2.

Source: NCI Genomic Data Commons file c2c6246a-a5cd-4da9-88a0-cc72706dada7 (TCGA-73-4675.73BE3E61-573D-43A3-A055-E86786E126F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).